Somatic mutation profile of tumor specimen TCGA-A3-A8CQ-01A (aliquot TCGA-A3-A8CQ-01A-11D-A36X-10) from TCGA case TCGA-A3-A8CQ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.1 years (21,572 days).
Specimen TCGA-A3-A8CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9643757a-8a74-4f20-9945-9fa06aa2ef3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A8CQ-10A (Blood Derived Normal), aliquot TCGA-A3-A8CQ-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8cb7fad-0791-4b73-a20c-41310fa79675

The open-access MAF lists 46 somatic variants for this specimen: 25 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 20, Frame Shift Del 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.2533A>G p.K845E | Missense Mutation (SNP) | VAF 132/422 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.339); catalogued as COSV100429957; called by muse, mutect2, varscan2
- ATG2A | c.155T>G p.I52S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101034781, COSV65965605; called by muse, mutect2, varscan2
- BRCA2 | c.8659T>A p.S2887T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV101204630; called by muse, mutect2, varscan2
- BRPF3 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV100326167; called by muse, mutect2
- CCDC39 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV99870576; called by muse, mutect2, varscan2
- CCDC87 | c.1608A>C p.K536N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100040175; called by muse, mutect2, varscan2
- DHX29 | c.3296C>A p.A1099E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99287700; called by muse, mutect2
- DNAH7 | c.11018A>G p.Y3673C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs770387590, COSV56773787; called by muse, mutect2, varscan2
- EMP2 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.158); catalogued as rs1452297350, COSV100852878, COSV63995874; called by muse, mutect2, varscan2
- GATB | c.128G>C p.S43T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as COSV99859295; called by muse, mutect2, varscan2
- GREM2 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100547975; called by muse, mutect2, varscan2
- HSPB6 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV99137505; called by muse, mutect2, varscan2
- MYH11 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs886038900, COSV55547028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1L | c.2847del p.I950Sfs*39 | Frame Shift Del (DEL) | VAF 43/208 reads (21%) | catalogued as COSV67703228; called by mutect2, pindel, varscan2
- NLRP2 | c.2113G>C p.A705P | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99672625; called by muse, mutect2
- RHPN1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs370418616; called by muse, mutect2, varscan2
- SBNO2 | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100684995; called by muse, mutect2, varscan2
- SELE | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100325126; called by muse, mutect2, varscan2
- SLC2A9 | c.1505C>A p.T502N | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99305528; called by muse, mutect2, varscan2
- SPSB4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1043710898, COSV60148298; called by muse, mutect2, varscan2
- WDR81 | c.4882A>C p.S1628R (on ENST00000409644 / NM_001163809.2; = p.S577R on NM_152348.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100489195; called by muse, mutect2, varscan2
- WNK3 | c.2741T>C p.I914T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100672074; called by muse, mutect2, varscan2
- ZHX2 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073875; called by muse, mutect2, varscan2
- DDX42 | c.1392del p.I464Mfs*8 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- PAM | c.1739del p.L580Cfs*5 | Frame Shift Del (DEL) | VAF 148/523 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.198C>T p.H66= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV101125378; called by muse, mutect2, varscan2
- DSP | c.4566G>A p.T1522= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1159243386, COSV101131739; called by muse, mutect2, varscan2
- FBN3 | c.6225C>A p.V2075= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs190952845, COSV99561781; called by muse, mutect2, varscan2
- FSTL5 | c.690C>T p.D230= | Silent (SNP) | VAF 102/292 reads (35%) | catalogued as COSV100054465, COSV60217671; called by muse, mutect2, varscan2
- KDM3B | c.573C>T p.F191= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs770604921, COSV100070212; called by muse, mutect2, varscan2
- MAP3K10 | c.1350C>T p.P450= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99454827; called by muse, mutect2, varscan2
- MGA | c.7101G>A p.L2367= (on ENST00000219905 / NM_001164273.1; = p.L2158= on NM_001080541.2) | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as COSV99581465; called by muse, mutect2, varscan2
- NBR1 | c.2031A>G p.T677= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100357994; called by muse, mutect2, varscan2
- NUP62CL | c.409T>C p.L137= | Silent (SNP) | VAF 94/305 reads (31%) | catalogued as rs1276891148, COSV100991069; called by muse, mutect2, varscan2
- RFXAP | c.762A>G p.L254= | Silent (SNP) | VAF 54/192 reads (28%) | catalogued as rs750527279, COSV99715222; called by muse, mutect2, varscan2
- SBNO2 | c.921C>T p.S307= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs368959645; called by muse, mutect2, varscan2
- SGK3 | c.693A>G p.Q231= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV100616862; called by muse, mutect2, varscan2
- SPOUT1 | c.282C>G p.T94= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100778259; called by muse, mutect2, varscan2
- STEAP3 | c.780G>A p.P260= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs1027167800, COSV61529631; called by muse, mutect2, varscan2
- SVOPL | c.1383C>A p.A461= (on ENST00000419765; = p.A309= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV99939625; called by muse, mutect2, varscan2
- TBL2 | c.1317G>A p.L439= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99979739; called by muse, mutect2, varscan2
- TRAPPC13 | c.195G>A p.L65= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV99198979; called by muse, mutect2, varscan2
- XIRP2 | c.4683T>C p.D1561= (on ENST00000628543; = p.D1736= on NM_152381.6) | Silent (SNP) | VAF 96/220 reads (44%) | catalogued as COSV99747102; called by muse, mutect2, varscan2
- YIPF7 | c.78A>C p.S26= | Silent (SNP) | VAF 64/211 reads (30%) | catalogued as COSV100274654; called by muse, mutect2, varscan2
- ZNF184 | c.588A>G p.Q196= | Silent (SNP) | VAF 153/515 reads (30%) | catalogued as COSV99280054; called by muse, mutect2, varscan2
- ARHGEF4 | c.1921+58T>G | Intron (SNP) | VAF 38/162 reads (23%) | catalogued as COSV100388655; called by muse, mutect2, varscan2
